Gene-level copy-number profile of tumor specimen ALCH-AD0E-TTP1-A from ALCHEMIST case ALCH-AD0E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,371 days).
Specimen ALCH-AD0E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4cdfcd9d-569f-45cc-bc1d-6d787422157d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD0E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/30ce3873-f71a-4fb1-b004-b616399469e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 9,738; copy number 2: 43,260; copy number 3: 5,100; copy number 4: 233; copy number 5: 16; copy number 7: 14; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,487,246–3,487,627, 1 gene: AL512413.1.
- chr1:223,976,146–223,976,249, 1 gene: RNU6-1319P.
- chr15:25,169,337–25,206,343, 21 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20.
- chr17:18,225,635–18,268,828, 4 genes: LLGL1, FLII, MIEF2, AC127537.1.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr17:39,687,914–39,730,532, 3 genes (within-gene range 0–2): ERBB2, MIR4728, MIEN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:8,621,683–9,408,093, 21 genes, copy number 5–7: METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177.
- chr16:9,541,970–9,614,899, 1 gene, copy number 5 (within-gene range 2–5): AC007221.1.
- chr16:9,600,097–10,182,928, 7 genes, copy number 5: RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11.
- chr18:45,034–46,047, 1 gene, copy number 5: AP001005.1.
- chr22:20,338,805–20,354,387, 3 genes, copy number 11 (within-gene range 1–11): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 9,684. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
